CPTAC case C3N-02271 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2586a0d7-90b6-403a-9025-5c0edeb34c87

Demographics
Sex at birth: female; Race: white; Year of birth: 1958; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 58.9 years (21,506 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,853 days (5.1 years); Progression or recurrence: no; Days to last follow up: 1,853 days (5.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 0.7 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 4; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 320 days; Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 700 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,063 days (2.9 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,328 days (3.6 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,328 days (3.6 years); Disease response: Complete Response; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,853 days (5.1 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.

Other clinical attributes
- Weight: 121 kg; Height: 158 cm; BMI: 48; Hormonal contraceptive use: Never Used.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02271-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -15 days; Initial weight: 176 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02271-21: Section location: Anterior endometrium; Percent tumor nuclei: 90; Percent necrosis: 5.
- Sample C3N-02271-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -15 days; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02271-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -12 days; Method of sample procurement: Blood Draw.
